Somatic mutation profile of tumor specimen 5a85e6e7-35ab-4ca9-ab62-707e77 (aliquot 5a85e6e7-35ab-4ca9-ab62-707e77_D6_1) from CPTAC case 14CO002, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II.
Specimen 5a85e6e7-35ab-4ca9-ab62-707e77: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3c1ea9b-4995-4b56-a1d4-70e2dc1fdca9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f089ce8f-3dd1-4cd5-8183-a9a0c4 (Blood Derived Normal), aliquot f089ce8f-3dd1-4cd5-8183-a9a0c4_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b5512a3-369a-45f9-b616-9e4c7889dad0

The open-access MAF lists 116 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Nonsense Mutation 3, Intron 3, Splice Region 3, Frame Shift Ins 2, 5'UTR 2, In Frame Del 1, RNA 1, Frame Shift Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 110/262 reads (42%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 16/52 reads (31%) | hotspot (GDC flag); called by pindel, varscan2
- ALPK1 | c.3026G>A p.R1009Q | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs141398762, COSV104385449, COSV51592685; called by muse, mutect2
- APC | c.509_512del p.D170Vfs*4 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs387906231; called by pindel, varscan2
- ARPIN | c.90G>A p.Q30= | Splice Region (SNP) | VAF 7/43 reads (16%) | catalogued as rs762313157; called by muse, mutect2, varscan2
- BFSP1 | c.1618C>A p.Q540K | Missense Mutation (SNP) | VAF 123/198 reads (62%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV64900967; called by muse, mutect2, varscan2
- BRSK1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs770275427; called by muse, varscan2
- CFAP47 | c.5092C>T p.R1698W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs749241599, COSV57971117; called by muse, mutect2, varscan2
- CHST5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 86/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358684012, COSV100291780; called by muse, mutect2, varscan2
- CLDN25 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs764892613, COSV71620422; called by muse, mutect2, varscan2
- CSAG3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 44/549 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1348141659; called by muse, mutect2
- CSHL1 | c.293C>T p.T98M (on ENST00000309894 / NM_022581.3; = p.T4M on NM_001318.4) | Missense Mutation (SNP) | VAF 60/710 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs149910727, COSV51987106; called by muse, mutect2
- CYP3A5 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 110/208 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs753861581, COSV56120084; called by muse, mutect2, varscan2
- DENND4A | c.5563C>T p.R1855* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs761943167, COSV101475363; called by muse, mutect2, varscan2
- EDRF1 | c.1904C>T p.P635L (on ENST00000356792 / NM_001202438.2; = p.P601L on NM_015608.2) | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs899525654; called by muse, mutect2, varscan2
- ESRRG | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100754051; called by muse, mutect2, varscan2
- FLT1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372354806; called by muse, mutect2, varscan2
- GDF10 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs782131518; called by muse, mutect2, varscan2
- GRIP1 | c.2020G>A p.V674M (on ENST00000359742 / NM_001379345.1; = p.V622M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs746921797, COSV54025464; called by muse, mutect2, varscan2
- HERC2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs370500858, COSV99873429; called by muse, mutect2, varscan2
- HYDIN | c.10231G>A p.V3411I | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs745949804; called by muse, mutect2, varscan2
- ITGA1 | c.1634T>C p.I545T | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs1177654268; called by muse, mutect2, varscan2
- ITSN1 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1251628654; called by muse, mutect2, varscan2
- KRT34 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 284/508 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748114147, COSV101222585; called by muse, mutect2, varscan2
- LIFR | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs781371324, COSV99665757; called by muse, mutect2, varscan2
- LYPLAL1 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1346652101; called by muse, mutect2, varscan2
- MAP1B | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1214277499; called by mutect2, varscan2
- MIER3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs768050096; called by muse, mutect2, varscan2
- MMP2 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 97/507 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs746451802; called by muse, mutect2, varscan2
- MPEG1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs574261219, COSV57090694; called by muse, mutect2, varscan2
- NAB2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as rs761753728; called by muse, mutect2
- NT5C1B | c.709C>T p.R237C (on ENST00000359846 / NM_001199086.2; = p.R177C on NM_033253.4) | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.91); catalogued as COSV58397243; called by muse, mutect2, varscan2
- PCDH17 | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs938421179, COSV64973271; called by muse, mutect2
- PCDHGB1 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV99547547; called by muse, mutect2
- PET100 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs535777992; called by muse, mutect2, varscan2
- PLEKHG2 | c.3938C>T p.T1313M | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs767068141; called by muse, mutect2, varscan2
- PNPLA6 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs1056939040; called by muse, mutect2, varscan2
- PRKD3 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 138/258 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750199145, COSV52211706; called by muse, mutect2, varscan2
- PRPH2 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 188/475 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs768400169, COSV57838562; called by mutect2, varscan2
- PYGL | c.2071G>A p.G691R | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539898848, COSV53588642; called by muse, mutect2
- SALL3 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144444322; called by muse, mutect2, varscan2
- SLC7A2 | c.1612G>A p.V538I (on ENST00000494857 / NM_001370338.1; = p.V577I on NM_003046.6) | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs145522409; called by muse, mutect2
- SLTM | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774877342, COSV51053969; called by muse, mutect2, varscan2
- SMPD1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as CM130682; called by muse, mutect2
- SNX17 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 199/390 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.38); catalogued as rs981370620, COSV104374030; called by muse, mutect2, varscan2
- SPHKAP | c.3196C>T p.R1066W | Missense Mutation (SNP) | VAF 130/272 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763842306, COSV60873618; called by muse, varscan2
- TANGO6 | c.1212G>T p.L404F | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV55761968; called by muse, mutect2, varscan2
- TENM4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.085); catalogued as rs754421992, COSV99574075; called by muse, mutect2, varscan2
- TMC6 | c.891G>A p.A297= | Splice Region (SNP) | VAF 264/438 reads (60%) | catalogued as rs762040968, COSV100130255; called by muse, mutect2, varscan2
- XIRP2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.595); catalogued as rs760433462, COSV54691555; called by muse, mutect2, varscan2
- ZBTB8A | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs201922748; called by muse, mutect2, varscan2
- ZNF804A | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 138/299 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs750487135, COSV100171076; called by muse, mutect2, varscan2
- APC | c.5390dup p.N1797Kfs*2 | Frame Shift Ins (INS) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- BAZ2B | c.5977C>T p.H1993Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- C9orf131 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 105/159 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CACNA2D2 | c.2601G>T p.Q867H (on ENST00000479441 / NM_001174051.3; = p.Q860H on NM_006030.4) | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHRNA6 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); called by muse, mutect2
- DHX33 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EBF2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.8286G>C p.M2762I | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- FOXM1 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by mutect2, varscan2
- HBS1L | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLV5-37 | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IRF2BP1 | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- KRT33B | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- MDGA2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MSH5 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- MYO3A | c.3290T>C p.L1097P | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NR2E1 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- OFD1 | c.313-4T>G | Splice Region (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- PCDH9 | c.1484A>T p.D495V | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLA2G4A | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRKAR2A | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SBK1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT1 | c.4475G>T p.C1492F | Missense Mutation (SNP) | VAF 143/452 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGDS | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIPAS39 | c.448-1G>A p.X150_splice | Splice Site (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- WASHC2A | c.3880G>A p.D1294N | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZBTB17 | c.1187dup p.K397Qfs*75 | Frame Shift Ins (INS) | VAF 110/357 reads (31%) | called by mutect2, pindel, varscan2
- ZNF516 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 133/225 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ABCA9 | c.3381C>T p.F1127= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV60625843; called by muse, varscan2
- ADCY2 | c.486C>T p.S162= | Silent (SNP) | VAF 97/275 reads (35%) | catalogued as rs200996412, COSV57886505; called by muse, mutect2, varscan2
- ADGRG4 | c.8835G>C p.L2945= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- CENPU | c.699C>T p.D233= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- CYFIP1 | c.6G>A p.A2= | Silent (SNP) | VAF 75/177 reads (42%) | catalogued as rs748234246; called by muse, mutect2, varscan2
- CYP11A1 | c.534C>T p.F178= | Silent (SNP) | VAF 78/314 reads (25%) | catalogued as rs150405116; called by muse, mutect2, varscan2
- DEF8 | c.831C>T p.R277= | Silent (SNP) | VAF 20/235 reads (9%) | called by muse, mutect2
- DGKI | c.2862T>C p.I954= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- DOCK4 | c.825C>A p.T275= | Silent (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- EPC2 | c.2262G>A p.S754= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs1327199529; called by muse, mutect2
- FAM219B | c.498C>T p.D166= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as rs552779646; called by muse, mutect2, varscan2
- GCDH | c.1299G>T p.A433= | Silent (SNP) | VAF 38/352 reads (11%) | called by mutect2, varscan2
- GIPC3 | c.669G>A p.R223= | Silent (SNP) | VAF 83/194 reads (43%) | called by muse, varscan2
- IRF4 | c.339G>A p.R113= | Silent (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- LRP2 | c.3840C>T p.N1280= | Silent (SNP) | VAF 57/316 reads (18%) | catalogued as rs767886006, COSV55547040; called by muse, mutect2, varscan2
- NEB | c.7749C>A p.I2583= | Silent (SNP) | VAF 28/378 reads (7%) | called by muse, mutect2
- NR3C2 | c.2898C>T p.D966= | Silent (SNP) | VAF 266/335 reads (79%) | called by muse, mutect2, varscan2
- OTOG | c.6111G>A p.A2037= | Silent (SNP) | VAF 88/227 reads (39%) | catalogued as rs562628744, COSV61133562; called by muse, mutect2, varscan2
- PAX8 | c.816C>T p.D272= | Silent (SNP) | VAF 39/240 reads (16%) | catalogued as COSV54511091; called by muse, mutect2, varscan2
- PCSK1 | c.909C>T p.F303= | Silent (SNP) | VAF 35/466 reads (8%) | catalogued as COSV60733876; called by muse, mutect2
- PCYT1B | c.636C>T p.D212= | Silent (SNP) | VAF 144/172 reads (84%) | called by muse, mutect2, varscan2
- PKD1L1 | c.8061C>G p.P2687= | Silent (SNP) | VAF 37/382 reads (10%) | called by muse, mutect2, varscan2
- RABGAP1L | c.2037G>A p.P679= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs1225703541, COSV52293022; called by muse, mutect2, varscan2
- SOX3 | c.342C>T p.A114= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1485470308, COSV65168829; called by muse, mutect2
- TEP1 | c.3354G>A p.L1118= | Silent (SNP) | VAF 46/169 reads (27%) | called by muse, mutect2, varscan2
- TSHZ3 | c.81C>T p.D27= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs745775592; called by muse, mutect2, varscan2
- VCX3A | c.231C>T p.S77= | Silent (SNP) | VAF 87/780 reads (11%) | catalogued as rs1488347380; called by muse, mutect2
- ZNF467 | c.801C>T p.T267= | Silent (SNP) | VAF 166/471 reads (35%) | catalogued as rs768406178, COSV57372032; called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824656 G>A | 3'Flank (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- CLEC16A | c.2641+49G>A | Intron (SNP) | VAF 87/216 reads (40%) | catalogued as rs201585756; called by muse, mutect2, varscan2
- DPY19L2P1 | n.1811+1581G>A | Intron (SNP) | VAF 34/101 reads (34%) | catalogued as rs777493086; called by muse, mutect2, varscan2
- FAM193A | c.-35G>A | 5'UTR (SNP) | VAF 57/314 reads (18%) | catalogued as rs1260009478; called by muse, mutect2, varscan2
- HACE1 | c.-37C>A | 5'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- MUC20P1 | n.1050C>A | RNA (SNP) | VAF 171/1064 reads (16%) | catalogued as rs1331272945; called by muse, mutect2, varscan2
- NEBL | c.2149-18dup | Intron (INS) | VAF 31/154 reads (20%) | called by mutect2, pindel, varscan2
- RNF170 | c.*1604A>G | 3'UTR (SNP) | VAF 116/428 reads (27%) | called by muse, mutect2, varscan2
